CCDI case PBBVYU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/b428cf0e-9e7c-46c6-bd3a-1b42b3d4d303

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Sphenoid sinus; Age at diagnosis: 8.7 years (3,178 days).

Biospecimens (3 samples)
- Sample 0DKGX7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKGXB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKGXG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
